MMRF case MMRF_1068 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fba98eb9-442c-415c-b109-bd02b4a71c82

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 564 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.3 years (21,303 days); ISS stage: I; Days to last known disease status: 564 days (1.5 years); Days to last follow up: 564 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 407 days (1.1 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 477 days (1.3 years); Days to treatment end: 535 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 564.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 69 mg/dL; Immunoglobulin G 54.6 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 3.03 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 10.3 g/dL; Glucose 4.51 mmol/L.
- Day 71: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 7.08 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.24 µg/mL; Lactate Dehydrogenase 8.3 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 11.7 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 4.35 mmol/L.
- Day 171: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 9.97 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.28 µg/mL; Lactate Dehydrogenase 7.47 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 6.05 mmol/L.
- Day 246 (ECOG 1): Hemoglobin 7.75 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 5.06 mmol/L.
- Day 372 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 463 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.32 mg/dL; Immunoglobulin G 5.56 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 1.51 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day -6: Weight: 96 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1068_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1068_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
